Somatic mutation profile of tumor specimen HCM-BROD-0613-C71-01A (aliquot HCM-BROD-0613-C71-01A-11D-A80U-36) from HCMI case HCM-BROD-0613-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.0 years (18,640 days).
Specimen HCM-BROD-0613-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de8ed43a-ac97-47ae-b4da-03695a00c576.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0613-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0613-C71-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df5c1847-23f4-4ff8-ae7c-abb16eed9842

The open-access MAF lists 38 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 10, Frame Shift Del 3, Intron 2, Splice Region 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 306/500 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKMY1 | c.220T>C p.Y74H | Missense Mutation (SNP) | VAF 85/234 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775170853; called by muse, mutect2, varscan2
- ANKRD33 | c.428G>A p.G143E (on ENST00000340970 / NM_001304459.2; = p.G268E on NM_182608.4) | Missense Mutation (SNP) | VAF 296/704 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV56608802; called by muse, mutect2
- BTBD16 | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 53/77 reads (69%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs577596137; called by muse, mutect2, varscan2
- CRACD | c.2236C>T p.R746* | Nonsense Mutation (SNP) | VAF 179/425 reads (42%) | catalogued as rs777119246, COSV51726266; called by muse, mutect2, varscan2
- DNAH3 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 129/308 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs528418539, COSV54544211; called by muse, mutect2, varscan2
- DPYSL3 | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 134/463 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs756369537, COSV58325727; called by muse, mutect2, varscan2
- EIF4G3 | c.3509G>A p.R1170Q | Missense Mutation (SNP) | VAF 164/390 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as rs541460610; called by muse, mutect2, varscan2
- LAMB4 | c.2231C>T p.P744L | Missense Mutation (SNP) | VAF 132/475 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV52721350; called by muse, mutect2, varscan2
- MAP7D3 | c.1238G>A p.S413N | Missense Mutation (SNP) | VAF 266/316 reads (84%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs758521409; called by muse, mutect2, varscan2
- MARCHF10 | c.1187C>G p.A396G | Missense Mutation (SNP) | VAF 173/378 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as rs376963369; called by muse, mutect2, varscan2
- MYOM3 | c.3621C>T p.D1207= | Splice Region (SNP) | VAF 80/226 reads (35%) | catalogued as rs372739261; called by muse, mutect2, varscan2
- NFIC | c.1175C>T p.T392M | Missense Mutation (SNP) | VAF 48/696 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs772596817; called by muse, mutect2
- PCDHGC4 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 153/511 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs372373315; called by muse, mutect2, varscan2
- SLC23A3 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 136/339 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as rs192655015; called by muse, mutect2, varscan2
- TEKT3 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 182/466 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs764367004, COSV100106876; called by muse, mutect2, varscan2
- TP53 | c.461del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 383/579 reads (66%) | catalogued as CM951223, COSV52667239, COSV52783646, COSV53625267; called by mutect2, pindel, varscan2
- CNBD1 | c.160del p.R54Gfs*3 | Frame Shift Del (DEL) | VAF 59/174 reads (34%) | called by mutect2, pindel, varscan2
- CNIH4 | c.75del p.T26Hfs*5 | Frame Shift Del (DEL) | VAF 53/133 reads (40%) | called by mutect2, pindel*, varscan2
- MSH4 | c.2779A>G p.T927A | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHS | c.2569G>A p.G857S | Missense Mutation (SNP) | VAF 195/214 reads (91%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPY1R | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 130/282 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PRKCG | c.1258C>G p.L420V | Missense Mutation (SNP) | VAF 167/436 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- RGPD3 | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- SLC26A1 | c.930G>C p.Q310H | Missense Mutation (SNP) | VAF 192/431 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- AHNAK | c.16338G>A p.R5446= | Silent (SNP) | VAF 161/356 reads (45%) | called by muse, mutect2, varscan2
- CCDC88C | c.2136G>A p.L712= | Silent (SNP) | VAF 177/371 reads (48%) | called by muse, mutect2, varscan2
- CLEC1B | c.498G>A p.S166= | Silent (SNP) | VAF 93/222 reads (42%) | catalogued as rs370262331; called by muse, mutect2, varscan2
- H4C8 | c.126C>T p.G42= | Silent (SNP) | VAF 550/598 reads (92%) | catalogued as rs144152120; called by muse, mutect2
- MCU | c.603G>A p.R201= | Silent (SNP) | VAF 121/156 reads (78%) | called by muse, mutect2, varscan2
- MGAM2 | c.612G>A p.Q204= | Silent (SNP) | VAF 154/520 reads (30%) | catalogued as rs1396281184; called by muse, mutect2, varscan2
- MMRN1 | c.1704C>T p.H568= | Silent (SNP) | VAF 102/272 reads (38%) | catalogued as rs781201120; called by muse, mutect2, varscan2
- OLFML2B | c.2031C>T p.F677= | Silent (SNP) | VAF 147/301 reads (49%) | catalogued as rs1346925350, COSV54194943; called by muse, mutect2, varscan2
- RBL1 | c.481C>A p.R161= | Silent (SNP) | VAF 43/228 reads (19%) | called by muse, mutect2, varscan2
- TAF11L14 | c.342G>A p.Q114= | Silent (SNP) | VAF 132/506 reads (26%) | called by muse, mutect2, varscan2
- DCHS2 | n.6657A>C | RNA (SNP) | VAF 172/409 reads (42%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-34474T>C | Intron (SNP) | VAF 39/258 reads (15%) | called by muse, varscan2
- MAST4 | c.675-67929C>A | Intron (SNP) | VAF 102/358 reads (28%) | called by muse, mutect2, varscan2
